Somatic mutation profile of tumor specimen C3N-02089-03 (aliquot CPT0118340006) from CPTAC case C3N-02089, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 76.4 years (27,910 days).
Specimen C3N-02089-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e35955c8-b746-482e-96c5-e6a910ffa288.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02089-31 (Blood Derived Normal), aliquot CPT0119570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/feaac4c4-14f5-4e77-8970-daddc41ef297

The open-access MAF lists 1,281 somatic variants for this specimen: 891 protein-altering or splice-affecting, 235 silent, 155 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 764, Silent 235, Intron 76, Nonsense Mutation 70, RNA 31, Frame Shift Del 28, 3'UTR 22, 5'UTR 12, Splice Site 12, Frame Shift Ins 8, 5'Flank 8, Splice Region 7.

Variants (750 of 1,281; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 42/174 reads (24%) | catalogued as rs1474063386, CM054642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.661); catalogued as rs1392647178; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1382C>G p.A461G | Missense Mutation (SNP) | VAF 99/498 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397509344, COSV61005273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 206/506 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD6 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs780341808; called by muse, mutect2
- ACE | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs750754792; called by muse, mutect2, varscan2
- ACY3 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54828388; called by muse, mutect2, varscan2
- ADAMTS16 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs187350862; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58441876; called by muse, varscan2
- ALPK2 | c.4323G>T p.M1441I | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs767137063; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1883G>A p.R628K | Missense Mutation (SNP) | VAF 68/570 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.125); catalogued as rs1462982063, COSV62003446; called by muse, mutect2, varscan2
- ANKRD30A | c.2083T>A p.S695T (on ENST00000611781; = p.S639T on NM_052997.2) | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.042); catalogued as rs1160176372; called by muse, mutect2, varscan2
- ANKRD30BL | c.286T>C p.C96R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1232698712; called by muse, mutect2
- AP3B2 | c.1153A>T p.T385S | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.435); catalogued as rs781524703; called by muse, mutect2, varscan2
- ARHGEF10L | c.1255A>G p.S419G | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs770914411; called by muse, mutect2, varscan2
- ARHGEF7 | c.2579C>G p.T860S (on ENST00000646102 / NM_001354046.1; = p.T644S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.226); catalogued as COSV54546174; called by muse, mutect2, varscan2
- ASXL3 | c.3704C>A p.S1235Y | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as rs1468967860, COSV52461645, COSV52474635; called by muse, mutect2
- ASXL3 | c.5771G>C p.G1924A | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs1240300038; called by muse, mutect2, varscan2
- ATP10B | c.2179C>A p.L727M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59146220; called by muse, mutect2, varscan2
- ATP6V0A2 | c.221G>T p.R74I | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV57747614, COSV57748415; called by muse, mutect2, varscan2
- B3GNT6 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs1213720736; called by muse, mutect2, varscan2
- BAZ1A | c.3578C>T p.P1193L | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270938185; called by muse, mutect2, varscan2
- BTBD11 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs764936824; called by muse, mutect2, varscan2
- BUB1 | c.3209G>T p.R1070L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs765636832, COSV99044092; called by muse, mutect2, varscan2
- C19orf81 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1419688962; called by muse, mutect2, varscan2
- C1QTNF2 | c.907G>T p.G303W (on ENST00000393975; = p.G258W on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67433275; called by muse, mutect2, varscan2
- C4orf19 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs543128145; called by muse, mutect2, varscan2
- CA10 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 32/189 reads (17%) | catalogued as COSV53345310; called by muse, mutect2, varscan2
- CACNA1A | c.5230T>G p.F1744V | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV100803193; called by muse, mutect2, varscan2
- CACNA1E | c.5978C>A p.A1993E | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as rs770927901; called by muse, mutect2
- CACNA2D4 | c.2320G>T p.G774C | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99765650, COSV99766365; called by muse, varscan2
- CACNA2D4 | c.2247G>A p.E749= | Splice Region (SNP) | VAF 32/215 reads (15%) | catalogued as rs1314490125; called by muse, varscan2
- CAMTA1 | c.4400C>T p.S1467F | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100352110; called by muse, mutect2, varscan2
- CBX4 | c.545G>C p.S182T | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV99490338; called by muse, mutect2
- CCDC40 | c.466del p.V156Sfs*11 | Frame Shift Del (DEL) | VAF 20/138 reads (14%) | catalogued as COSV53901859; called by mutect2, pindel, varscan2
- CCNY | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1338942848; called by muse, mutect2
- CD180 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs944173529; called by muse, mutect2, varscan2
- CDH16 | c.1715G>T p.S572I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs1367555173; called by muse, mutect2, varscan2
- CDH2 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 71/289 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.904); catalogued as COSV99295857; called by muse, mutect2, varscan2
- CDK14 | c.826G>T p.G276C (on ENST00000380050 / NM_001287135.2; = p.G258C on NM_012395.3) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56049976, COSV56057033; called by muse, mutect2, varscan2
- CDKN1A | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 150/405 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs746781060; called by muse, mutect2, varscan2
- CDKN1B | c.410del p.P137Rfs*8 | Frame Shift Del (DEL) | VAF 18/179 reads (10%) | catalogued as rs1328655695, COSV99964122; called by mutect2, pindel
- CERCAM | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs768275632, COSV65710643; called by muse, mutect2, varscan2
- CFAP52 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100235045; called by muse, mutect2, varscan2
- CFAP54 | c.7575A>T p.E2525D | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs1247911196; called by muse, mutect2
- CFH | c.2000G>C p.G667A | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104427247; called by muse, mutect2, varscan2
- CHODL | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs753271143, COSV54732982; called by muse, mutect2, varscan2
- CHRNA3 | c.612C>G p.S204R | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58774153; called by muse, mutect2, varscan2
- CHRNA4 | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 113/620 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.179); catalogued as rs1292158071; called by muse, mutect2, varscan2
- CHRNA4 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as rs370553755; called by muse, mutect2, varscan2
- CNGB3 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 116/490 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60692245; called by muse, mutect2, varscan2
- CNGB3 | c.692G>T p.W231L | Missense Mutation (SNP) | VAF 94/386 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV60699642; called by muse, mutect2, varscan2
- CNTN5 | c.1305G>T p.R435S | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs995784320; called by muse, mutect2, varscan2
- COL12A1 | c.5606G>T p.G1869V | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277824128; called by muse, mutect2, varscan2
- COL14A1 | c.2563C>A p.P855T | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV99920082; called by muse, varscan2
- COL20A1 | c.3706G>T p.G1236W | Missense Mutation (SNP) | VAF 107/293 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV58915165; called by muse, mutect2, varscan2
- COL3A1 | c.2194G>T p.G732* | Nonsense Mutation (SNP) | VAF 34/366 reads (9%) | catalogued as CM119023; called by muse, mutect2
- COL5A1 | c.3287G>C p.G1096A | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99057226; called by muse, mutect2, varscan2
- COL6A3 | c.1383C>A p.F461L | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV55080483, COSV55086102; called by muse, mutect2
- CR1 | c.5231G>C p.R1744P | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV65456601; called by muse, varscan2
- CRACDL | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV101194095; called by muse, mutect2, varscan2
- CRISP1 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV59994129, COSV59995006; called by muse, mutect2, varscan2
- CRP | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 46/480 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54814786; called by muse, mutect2
- CRTAC1 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085740; called by muse, mutect2, varscan2
- CSF2RB | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 142/546 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as COSV53258618; called by muse, mutect2, varscan2
- CSMD1 | c.2967G>T p.E989D (on ENST00000520002; = p.E988D on NM_033225.6) | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV59365023; called by muse, mutect2, varscan2
- CSMD1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs752440260, COSV68173715, COSV68217391; called by muse, mutect2, varscan2
- CTNNA1 | c.2536T>A p.S846T | Missense Mutation (SNP) | VAF 14/369 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV57069726; called by muse, mutect2
- CTNND2 | c.3633C>A p.N1211K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs781186044; called by muse, varscan2
- CTU1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV70292214; called by muse, varscan2
- CUBN | c.7033G>T p.G2345C | Missense Mutation (SNP) | VAF 112/328 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773678740; called by muse, mutect2, varscan2
- DCC | c.4168G>C p.A1390P | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); catalogued as COSV71431781; called by muse, mutect2, varscan2
- DDX3X | c.1870G>T p.G624* (on ENST00000399959; = p.G625* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV67863805; called by muse, mutect2, varscan2
- DNAH5 | c.12037C>T p.R4013C | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs148349630; called by muse, mutect2, varscan2
- DNAJC13 | c.3499A>G p.I1167V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1221814534; called by muse, varscan2
- DOK6 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 56/150 reads (37%) | catalogued as COSV66935496; called by muse, mutect2, varscan2
- DYNC1H1 | c.3571C>T p.R1191C | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs774198261, COSV64136618; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFLAM | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59309069; called by muse, mutect2, varscan2
- EPB41L2 | c.1762C>A p.Q588K | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100440431; called by muse, mutect2, varscan2
- EPB41L3 | c.305A>T p.K102M | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100550437; called by muse, mutect2, varscan2
- EPB41L5 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55358888; called by muse, mutect2, varscan2
- EPHA5 | c.2630G>T p.R877I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56660894; called by muse, mutect2, varscan2
- EPHA6 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67570115; called by muse, mutect2, varscan2
- ETV3L | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 31/417 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.475); catalogued as COSV71901214; called by muse, mutect2
- FAM135B | c.986C>A p.S329Y | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52709845, COSV99421515; called by muse, mutect2, varscan2
- FAM160A1 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV70706219; called by muse, mutect2
- FAM167B | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1457559720, COSV100405968; called by muse, mutect2, varscan2
- FAM189A1 | c.669del p.C223Wfs*2 | Frame Shift Del (DEL) | VAF 31/166 reads (19%) | catalogued as COSV54290481; called by mutect2, pindel, varscan2
- FASLG | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 40/174 reads (23%) | catalogued as COSV60680460; called by muse, mutect2, varscan2
- FAT1 | c.1629G>T p.W543C | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV71674861; called by muse, mutect2, varscan2
- FAT2 | c.7658T>C p.I2553T | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs140194858; called by muse, mutect2, varscan2
- FAT3 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs1182531461; called by muse, mutect2, varscan2
- FBLN2 | c.2745C>A p.H915Q | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.178); catalogued as rs1216024202; called by muse, mutect2, varscan2
- FCRL3 | c.1863G>T p.E621D | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV100943478; called by muse, mutect2, varscan2
- FGFR2 | c.1522C>G p.P508A | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV60655125; called by muse, mutect2
- FICD | c.722C>A p.S241* | Nonsense Mutation (SNP) | VAF 74/438 reads (17%) | catalogued as COSV99933790; called by muse, mutect2, varscan2
- FLG | c.11405G>A p.G3802E | Missense Mutation (SNP) | VAF 61/716 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs753492442; called by muse, mutect2
- FOXK2 | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV100082330; called by muse, mutect2
- FOXR1 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 46/304 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV57651236; called by muse, mutect2, varscan2
- FSIP2 | c.16223C>A p.S5408* | Nonsense Mutation (SNP) | VAF 49/184 reads (27%) | catalogued as COSV58079283, COSV58093971; called by muse, mutect2, varscan2
- GALNT17 | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.368); catalogued as rs985839732, COSV61193232; called by muse, mutect2, varscan2
- GNRHR | c.931T>C p.F311L | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV56932895; called by muse, mutect2, varscan2
- GPANK1 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381181010; called by muse, mutect2, varscan2
- GRAMD1A | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100525936; called by muse, mutect2, varscan2
- GRIK2 | c.2548G>T p.A850S | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as COSV59711603, COSV59784402; called by muse, mutect2, varscan2
- GRIN2A | c.4380C>G p.I1460M | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs769629103, COSV58029601; called by muse, mutect2, varscan2
- GUCY2D | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 94/397 reads (24%) | catalogued as rs1349155167; called by muse, mutect2, varscan2
- HCN1 | c.849+1G>C p.X283_splice | Splice Site (SNP) | VAF 14/144 reads (10%) | catalogued as COSV100303216; called by muse, mutect2
- HCN1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.034); catalogued as rs56164833; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- HDGFL1 | c.138C>A p.H46Q | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100014557; called by muse, mutect2, varscan2
- HMCN1 | c.7666G>T p.A2556S | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99637443; called by muse, mutect2
- HMX3 | c.806C>G p.T269R | Missense Mutation (SNP) | VAF 31/335 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317350675; called by muse, mutect2
- HOXA1 | c.183C>G p.I61M | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs761654698; called by muse, varscan2
- HOXA4 | c.112G>T p.G38W | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs746129531, COSV57825070; called by muse, mutect2, varscan2
- HSD17B2 | c.965T>A p.L322Q | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99077054; called by muse, mutect2, varscan2
- IGDCC3 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs766501573, COSV60078951; called by muse, mutect2, varscan2
- IGHV2-26 | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 72/596 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1171836241; called by muse, mutect2, varscan2
- IGSF10 | c.4946G>T p.R1649M | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV104390207; called by muse, mutect2, varscan2
- IMPG1 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs759925201; called by muse, mutect2, varscan2
- INHBA | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV54221694; called by muse, mutect2, varscan2
- INTS2 | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1479130291; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101188149; called by muse, mutect2
- JMJD1C | c.784C>G p.R262G | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67861404; called by muse, mutect2
- KALRN | c.232G>T p.V78L | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.99); catalogued as COSV99563909; called by muse, mutect2, varscan2
- KCNA4 | c.1500G>T p.E500D | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100069304; called by muse, mutect2, varscan2
- KIAA0825 | c.1916G>T p.C639F | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs938212176; called by muse, mutect2, varscan2
- KIFC2 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.867); catalogued as rs201694783, COSV104398459; called by muse, mutect2, varscan2
- KNDC1 | c.1512C>T p.N504= | Splice Region (SNP) | VAF 118/263 reads (45%) | catalogued as rs755288859, COSV58839894; called by muse, mutect2, varscan2
- KRT24 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1165603150, COSV99232119; called by muse, mutect2, varscan2
- KRT6B | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 61/558 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754808789, COSV52884532; called by muse, mutect2, varscan2
- LCE5A | c.189G>C p.E63D | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.048); catalogued as COSV57500331; called by muse, mutect2, varscan2
- LCN9 | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV52992453; called by muse, mutect2, varscan2
- LCP2 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV50457655, COSV99252280; called by muse, mutect2, varscan2
- LRRC66 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1407545097; called by muse, mutect2, varscan2
- LRRIQ1 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV101279240; called by muse, mutect2, varscan2
- MAG | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764252583, COSV62701894; called by muse, mutect2, varscan2
- MARCHF7 | c.21G>T p.R7S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99374183; called by muse, mutect2
- MASP1 | c.1249C>A p.Q417K | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99397577; called by muse, mutect2, varscan2
- MCIDAS | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1561114422; called by muse, mutect2, varscan2
- MDN1 | c.3421G>T p.A1141S | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs890731464; called by muse, varscan2
- MUC16 | c.25528del p.L8510Sfs*27 | Frame Shift Del (DEL) | VAF 43/192 reads (22%) | catalogued as COSV67480922; called by mutect2, pindel, varscan2
- MUC16 | c.24783A>T p.E8261D | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV101202321, COSV67456553; called by muse, mutect2, varscan2
- MXRA5 | c.2458C>G p.P820A | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as COSV54245592; called by muse, mutect2, varscan2
- MYH1 | c.5002C>A p.Q1668K | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV56851003; called by muse, mutect2
- MYH13 | c.4515G>T p.E1505D | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV52823218; called by muse, mutect2, varscan2
- MYMK | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV60600028; called by muse, mutect2, varscan2
- MYO7B | c.1000A>G p.M334V | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs376479682; called by muse, varscan2
- NAP1L2 | c.940T>C p.Y314H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.287); catalogued as COSV65172752; called by muse, mutect2, varscan2
- NBAS | c.1133G>T p.R378I | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs746801313, COSV55737584; called by muse, mutect2, varscan2
- NCAPD3 | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1462274104; called by muse, mutect2, varscan2
- NEB | c.5060G>C p.W1687S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1377396937, COSV51442504; called by muse, mutect2
- NECAB3 | c.643G>T p.G215W | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55775083; called by muse, mutect2, varscan2
- NECTIN4 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 211/659 reads (32%) | catalogued as COSV63511980; called by muse, mutect2, varscan2
- NFASC | c.253G>T p.A85S (on ENST00000339876 / NM_001378329.1; = p.A79S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as COSV58365528; called by muse, mutect2, varscan2
- NMRK2 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV51455617; called by muse, mutect2, varscan2
- NOL6 | c.2822G>A p.R941Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53041200, COSV53044759; called by muse, mutect2, varscan2
- NOTCH4 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 179/387 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260037526; called by muse, mutect2, varscan2
- NR2F2 | c.274G>C p.G92R | Missense Mutation (SNP) | VAF 85/507 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101240991; called by muse, mutect2, varscan2
- NT5C1B | c.895C>T p.P299S (on ENST00000359846 / NM_001199086.2; = p.P239S on NM_033253.4) | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99062468; called by muse, varscan2
- OR10A7 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 69/320 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as COSV58277984; called by muse, mutect2, varscan2
- OR1J4 | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100534295; called by muse, mutect2, varscan2
- OR1L1 | c.506C>A p.A169D (on ENST00000373686; = p.A119D on NM_001005236.3) | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564229495; called by muse, mutect2, varscan2
- OR2T34 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as COSV100170449, COSV60902062; called by muse, mutect2, varscan2
- OR4C3 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60587131; called by muse, mutect2, varscan2
- OR4D9 | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs948025673; called by muse, mutect2, varscan2
- OR4K1 | c.315C>A p.H105Q | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53461830, COSV99578979; called by muse, mutect2, varscan2
- OR51T1 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59023866; called by muse, mutect2, varscan2
- OR5H6 | c.553T>C p.C185R (on ENST00000642105; = p.C169R on NM_001005479.2) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs771140962; called by muse, mutect2, varscan2
- OR6Y1 | c.413C>A p.P138Q | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs372677915; called by muse, mutect2, varscan2
- OSBPL6 | c.348A>C p.L116F | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51923163; called by muse, mutect2, varscan2
- PCDHA2 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 135/492 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV65368946; called by muse, mutect2, varscan2
- PCDHA8 | c.1617C>A p.D539E | Missense Mutation (SNP) | VAF 213/710 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100969991; called by muse, mutect2, varscan2
- PCDHGA2 | c.1883C>A p.T628K | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53920803; called by muse, mutect2, varscan2
- PDSS2 | c.1045C>G p.R349G | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.314); catalogued as rs370370070; called by muse, mutect2
- PEG10 | c.839G>T p.R280L (on ENST00000482108 / NM_001040152.2; = p.R314L on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV71788507; called by muse, mutect2, varscan2
- PFKM | c.1959C>A p.D653E | Missense Mutation (SNP) | VAF 40/406 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs746885603; called by muse, mutect2
- PIEZO1 | c.3022G>A p.G1008R | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs368019686; called by muse, mutect2, varscan2
- PIK3C2G | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV56811159; called by muse, mutect2
- PJA1 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 23/135 reads (17%) | catalogued as COSV64053775; called by muse, mutect2, varscan2
- PKD1 | c.8408G>C p.G2803A | Missense Mutation (SNP) | VAF 50/506 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV51922811; called by muse, mutect2, varscan2
- PKHD1 | c.4333G>T p.V1445F | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV61877721; called by muse, mutect2, varscan2
- PLA2R1 | c.1971G>T p.E657D | Missense Mutation (SNP) | VAF 38/320 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.15); catalogued as COSV51785107; called by muse, mutect2, varscan2
- PLEKHM1 | c.2753T>C p.I918T | Missense Mutation (SNP) | VAF 45/348 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs767160296; called by muse, mutect2, varscan2
- PLXNA2 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs1261812536; called by muse, mutect2, varscan2
- PLXNB1 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.158); catalogued as COSV99602366; called by muse, mutect2, varscan2
- POLQ | c.3149G>C p.R1050P | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as rs772724619, COSV51756415; called by muse, mutect2, varscan2
- POM121L12 | c.223A>T p.T75S | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV101374914; called by muse, mutect2, varscan2
- POM121L2 | c.858A>G p.I286M | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.387); catalogued as COSV66277079; called by muse, mutect2, varscan2
- PPHLN1 | c.1350G>T p.K450N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV99871446; called by muse, mutect2, varscan2
- PPP1R15A | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 35/192 reads (18%) | catalogued as COSV99079369, COSV99565785; called by muse, mutect2, varscan2
- PPP2R2C | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs770960380; called by muse, mutect2, varscan2
- PRDM9 | c.1398G>T p.R466S | Missense Mutation (SNP) | VAF 97/445 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs755834976, COSV57003605, COSV57012633, COSV57014286; called by muse, mutect2, varscan2
- PRH2 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 14/322 reads (4%) | catalogued as rs374103538; called by muse, mutect2
- PRR23A | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV67213803; called by muse, mutect2, varscan2
- PTCHD4 | c.1673T>C p.L558P | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775348786; called by muse, mutect2, varscan2
- PTPRN | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV55353136; called by muse, mutect2, varscan2
- PUS1 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59036551; called by muse, mutect2, varscan2
- QSOX2 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.057); catalogued as COSV100699676; called by muse, mutect2, varscan2
- RIF1 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs1454780884; called by muse, mutect2, varscan2
- RYR1 | c.9868G>T p.E3290* | Nonsense Mutation (SNP) | VAF 82/400 reads (21%) | catalogued as CM091769, COSV100614823; called by muse, mutect2, varscan2
- SALL3 | c.3295G>A p.A1099T | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV73305759; called by muse, mutect2, varscan2
- SELE | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV60976471; called by muse, varscan2
- SEMA5A | c.2920G>A p.V974M | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs529504980, COSV66807638; called by muse, mutect2, varscan2
- SEZ6L | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV99961267; called by muse, mutect2, varscan2
- SEZ6L2 | c.2390T>A p.F797Y (on ENST00000308713 / NM_001114099.3; = p.F727Y on NM_012410.4) | Missense Mutation (SNP) | VAF 49/348 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.671); catalogued as COSV100435996; called by muse, mutect2, varscan2
- SIRPG | c.635G>T p.R212M | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV53809282; called by muse, mutect2, varscan2
- SLC11A2 | c.290G>C p.R97P (on ENST00000394904 / NM_001379455.1; = p.R68P on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/357 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50370614; called by muse, mutect2, varscan2
- SLC17A9 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs781724966; called by muse, mutect2, varscan2
- SLC8B1 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as COSV52526334; called by muse, mutect2
- SMYD1 | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.816); catalogued as rs1366714288; called by muse, mutect2, varscan2
- STK11 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 42/148 reads (28%) | catalogued as CM102315, COSV58824679; called by muse, mutect2, varscan2
- SYNE1 | c.12053C>T p.S4018L (on ENST00000367255 / NM_182961.4; = p.S3947L on NM_033071.3) | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54956254; called by muse, mutect2, varscan2
- SYT10 | c.1430G>T p.G477V | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57338992; called by muse, mutect2, varscan2
- SYT10 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749660933, COSV99951497; called by muse, mutect2, varscan2
- TAAR6 | c.217T>C p.S73P | Missense Mutation (SNP) | VAF 27/239 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51583613; called by muse, mutect2, varscan2
- TBC1D1 | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs752876991; called by muse, mutect2, varscan2
- TECRL | c.435+1G>T p.X145_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as COSV101168883; called by muse, mutect2, varscan2
- TF | c.1068T>A p.D356E | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301549727; called by muse, mutect2, varscan2
- TG | c.7421G>T p.G2474V | Missense Mutation (SNP) | VAF 55/324 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1224979983; called by muse, mutect2, varscan2
- THBS2 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.376); catalogued as COSV100827554; called by muse, mutect2, varscan2
- THSD7B | c.88C>A p.H30N | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV99750623; called by muse, mutect2, varscan2
- TIAM1 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV54547270; called by muse, mutect2, varscan2
- TMC2 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV62651063; called by muse, mutect2, varscan2
- TMIGD2 | c.721T>A p.C241S | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs554333681; called by muse, mutect2, varscan2
- TMPRSS11A | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV58358753; called by muse, mutect2, varscan2
- TNC | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 86/332 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60783393; called by muse, mutect2, varscan2
- TPR | c.3368A>T p.Q1123L | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV66601444; called by muse, mutect2, varscan2
- TRAV30 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.793); catalogued as rs1394899968; called by muse, mutect2, varscan2
- TRHDE | c.2187-1G>A p.X729_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as COSV53831560; called by muse, mutect2, varscan2
- TRIB1 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61335096; called by muse, mutect2
- TRIO | c.5609del p.P1870Rfs*26 | Frame Shift Del (DEL) | VAF 29/138 reads (21%) | catalogued as COSV60082883; called by mutect2, pindel, varscan2
- TRPA1 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 51/218 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51567551; called by muse, mutect2, varscan2
- TSR3 | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.057); catalogued as rs1377379057; called by muse, mutect2, varscan2
- TTN | c.15527G>A p.G5176D (on ENST00000591111; = p.G4249D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | PolyPhen probably damaging (0.993); catalogued as rs1418252439; called by muse, mutect2, varscan2
- TTPA | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV99478355; called by muse, mutect2
- UBQLN3 | c.1303A>G p.T435A | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs776572297; called by muse, mutect2, varscan2
- UNC79 | c.1627G>A p.D543N (on ENST00000393151 / NM_001346218.2; = p.D366N on NM_020818.5) | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV56415519; called by muse, mutect2, varscan2
- USP39 | c.868T>G p.F290V | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100084172; called by muse, mutect2, varscan2
- VN1R4 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV100237413; called by muse, mutect2, varscan2
- WDR43 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV56099745; called by muse, mutect2, varscan2
- WNK2 | c.6235G>T p.V2079F (on ENST00000297954 / NM_001282394.1; = p.V2042F on NM_006648.3) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52966696; called by muse, mutect2, varscan2
- ZEB2 | c.453A>C p.R151S | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.702); catalogued as rs758233583; called by muse, mutect2, varscan2
- ZMAT1 | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs754251317; called by muse, mutect2, varscan2
- ZMYM1 | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs772788048; called by mutect2, varscan2
- ZNF169 | c.845G>C p.R282T | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV61766310; called by muse, mutect2, varscan2
- ZNF208 | c.1070C>A p.T357N | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV104432313; called by muse, mutect2, varscan2
- ZNF215 | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.603); catalogued as rs761775300; called by muse, mutect2, varscan2
- ZNF233 | c.513T>A p.N171K | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV61934026; called by muse, mutect2, varscan2
- ZNF423 | c.1422C>A p.N474K (on ENST00000563137 / NM_001379286.1; = p.N466K on NM_015069.4) | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.078); catalogued as COSV52189641; called by muse, mutect2, varscan2
- ZNF45 | c.234A>T p.S78= | Splice Region (SNP) | VAF 38/198 reads (19%) | catalogued as COSV54192949; called by muse, mutect2, varscan2
- ZNF492 | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV101514036; called by muse, mutect2
- ZNF621 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs769362004, COSV100182860; called by muse, mutect2, varscan2
- ZNF716 | c.918C>A p.S306R | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs782571052; called by muse, mutect2, varscan2
- ZNF775 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs747202943; called by muse, mutect2, varscan2
- ZNF81 | c.280G>T p.G94W | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV58576903; called by muse, mutect2, varscan2
- ZNF835 | c.892C>A p.R298S | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.554); catalogued as rs1360023842; called by muse, mutect2, varscan2
- ZSCAN1 | c.803C>A p.T268N | Missense Mutation (SNP) | VAF 75/479 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.284); catalogued as rs903356419; called by muse, mutect2, varscan2
- ABCA5 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 17/172 reads (10%) | called by muse, mutect2, varscan2
- ABCA7 | c.2498A>C p.Q833P | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCC9 | c.1750C>G p.P584A | Missense Mutation (SNP) | VAF 35/338 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABHD16B | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 75/424 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ABI3BP | c.2307G>A p.L769= | Splice Region (SNP) | VAF 34/98 reads (35%) | called by muse, varscan2
- AC245033.1 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 241/764 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ACACA | c.4298G>T p.C1433F | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ACACB | c.855G>T p.E285D | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTL10 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- ACTN2 | c.2006G>T p.G669V | Missense Mutation (SNP) | VAF 135/387 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM28 | c.1990+1G>T p.X664_splice | Splice Site (SNP) | VAF 27/171 reads (16%) | called by muse, mutect2, varscan2
- ADAM29 | c.1960C>G p.L654V | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ADAM33 | c.903C>A p.L301= | Splice Region (SNP) | VAF 13/60 reads (22%) | called by muse, varscan2
- ADCY1 | c.970C>A p.L324M | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY6 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 66/362 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRB2 | c.4427A>T p.H1476L (on ENST00000373658 / NM_001364857.2; = p.H1475L on NM_001294335.2) | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRF5 | c.3817-2A>G p.X1273_splice | Splice Site (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- ADGRG6 | c.3137A>T p.Q1046L | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADHFE1 | c.956T>G p.I319S | Missense Mutation (SNP) | VAF 30/335 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2
- AFF2 | c.3545C>A p.S1182Y | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFF3 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- AGBL1 | c.526A>T p.K176* | Nonsense Mutation (SNP) | VAF 74/245 reads (30%) | called by muse, mutect2, varscan2
- AGFG1 | c.1035G>T p.Q345H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- AGRN | c.16C>G p.H6D | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.12467G>T p.G4156V | Missense Mutation (SNP) | VAF 78/322 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKNAD1 | c.2172T>A p.F724L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKTIP | c.709A>G p.S237G | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ALDH2 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALDH4A1 | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ALMS1 | c.1942del p.V648Ffs*25 | Frame Shift Del (DEL) | VAF 31/186 reads (17%) | called by mutect2, pindel, varscan2
- ALOX15 | c.809G>C p.G270A | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ALOX5 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALOX5 | c.1439A>T p.E480V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- AMER2 | c.385A>T p.S129C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANKRD12 | c.4688T>G p.V1563G | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.116); called by muse, mutect2
- ANKRD13C | c.570del p.R190Sfs*3 | Frame Shift Del (DEL) | VAF 25/122 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD17 | c.6967G>T p.V2323F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); called by muse, varscan2
- ANKRD30A | c.2084C>A p.S695* (on ENST00000611781; = p.S639* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | called by mutect2, varscan2
- ANKRD30A | c.3930C>A p.N1310K (on ENST00000611781; = p.N1254K on NM_052997.2) | Missense Mutation (SNP) | VAF 65/248 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ANKRD30B | c.3565C>A p.H1189N | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ANKRD30BL | c.175A>C p.K59Q | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ANKRD36C | c.3265G>T p.V1089L | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, mutect2
- ANKRD55 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ANKS1B | c.2968G>T p.V990F | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ANO5 | c.1181-1G>A p.X394_splice | Splice Site (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2, varscan2
- APC | c.7942del p.A2648Hfs*12 | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | called by mutect2, pindel, varscan2
- ARL13A | c.25T>A p.C9S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ASPM | c.8608T>G p.F2870V | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ATAD5 | c.2115A>C p.Q705H | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ATP13A4 | c.152A>T p.Y51F | Missense Mutation (SNP) | VAF 85/309 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ATP1A3 | c.2759C>A p.T920N (on ENST00000545399 / NM_001256214.2; = p.T907N on NM_152296.5) | Missense Mutation (SNP) | VAF 110/518 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ATP6V1C1 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 28/271 reads (10%) | called by muse, mutect2
- ATP8B2 | c.3351C>A p.F1117L (on ENST00000672630; = p.F1084L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.017); called by muse, mutect2
- ATRNL1 | c.3308G>A p.R1103K | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ATXN2 | c.2060C>G p.T687S (on ENST00000550104; = p.T527S on NM_002973.4) | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- B3GALT5 | c.601A>G p.S201G | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- B3GNT6 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- B4GALT1 | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 100/426 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- BABAM2 | c.989T>G p.V330G | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- BCAN | c.1883A>T p.Q628L | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- BCL2 | c.713A>T p.H238L | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- BCL2A1 | c.223A>C p.M75L | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- BFSP1 | c.1527G>T p.Q509H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 16/179 reads (9%) | called by muse, mutect2
- BMP10 | c.593G>T p.W198L | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB6 | c.1325T>C p.V442A | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BPTF | c.5591G>T p.R1864L | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRWD1 | c.994T>C p.F332L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- BTF3 | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- BUD23 | c.86+6G>T | Splice Region (SNP) | VAF 64/258 reads (25%) | called by muse, mutect2, varscan2
- C10orf71 | c.2696G>A p.W899* | Nonsense Mutation (SNP) | VAF 50/244 reads (20%) | called by muse, varscan2
- C10orf71 | c.2791G>C p.A931P | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); called by muse, varscan2
- C1QTNF6 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1RL | c.1309G>T p.G437C | Missense Mutation (SNP) | VAF 174/395 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf74 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C2orf78 | c.1864C>G p.P622A | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- CACNA1F | c.2874C>G p.H958Q | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CALCR | c.160A>T p.K54* | Nonsense Mutation (SNP) | VAF 48/149 reads (32%) | called by muse, mutect2, varscan2
- CALCRL | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CAMTA1 | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CAMTA1 | c.2971G>T p.A991S | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CBY2 | c.944C>A p.P315Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- CCDC166 | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CCDC168 | c.5182G>T p.G1728C | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CCDC197 | c.496A>C p.N166H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.319); called by muse, mutect2
- CCDC40 | c.1807G>T p.E603* | Nonsense Mutation (SNP) | VAF 114/436 reads (26%) | called by muse, mutect2, varscan2
- CD109 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD1E | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CD2 | c.255G>T p.K85N | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CD80 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CDC45 | c.1675G>T p.D559Y | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH6 | c.1391-1G>T p.X464_splice | Splice Site (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2
- CDHR2 | c.3713C>G p.S1238C | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CELSR3 | c.4424A>T p.E1475V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CEP104 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP250 | c.6748G>T p.E2250* | Nonsense Mutation (SNP) | VAF 40/225 reads (18%) | called by muse, mutect2, varscan2
- CEP295 | c.2639A>G p.E880G | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CFAP99 | c.965A>T p.K322M | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- CHADL | c.643_645del p.H215del | In Frame Del (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2
- CHD5 | c.993G>T p.R331S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2
- CHODL | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CKMT1B | c.1205G>C p.R402T | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLCNKA | c.1162del p.W388Gfs*21 | Frame Shift Del (DEL) | VAF 48/276 reads (17%) | called by mutect2, varscan2
- CLEC2D | c.481G>T p.G161* | Nonsense Mutation (SNP) | VAF 48/225 reads (21%) | called by muse, mutect2, varscan2
- CLEC4G | c.595C>G p.H199D | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CLPTM1 | c.898A>T p.S300C | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); called by muse, mutect2
- CNGA3 | c.812C>A p.P271Q | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CNMD | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP5 | c.1250T>A p.L417Q | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- COL11A2 | c.4846A>G p.R1616G (on ENST00000341947 / NM_080680.3; = p.R1509G on NM_080679.2) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- COL20A1 | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | called by muse, mutect2, varscan2
- COL24A1 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL6A6 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPT1A | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 56/377 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPXM2 | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.06); called by muse, mutect2, varscan2
- CRNN | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 69/353 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CROCC | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CRTAM | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CSHL1 | c.386C>A p.T129N (on ENST00000309894 / NM_022581.3; = p.T35N on NM_001318.4) | Missense Mutation (SNP) | VAF 70/327 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- CSMD3 | c.919T>C p.L307= | Splice Region (SNP) | VAF 40/318 reads (13%) | called by muse, mutect2, varscan2
- CT83 | c.83C>G p.T28S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, varscan2
- CTAGE1 | c.2125G>A p.V709I | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CTNND2 | c.2572T>A p.S858T | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CTNND2 | c.2121T>G p.H707Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CUBN | c.7034G>T p.G2345V | Missense Mutation (SNP) | VAF 112/328 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUX1 | c.1552T>G p.S518A | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CUX1 | c.1435C>G p.L479V (on ENST00000437600 / NM_181500.4; = p.L481V on NM_001913.5) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DCX | c.783G>T p.Q261H | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- DEPTOR | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKQ | c.1220A>T p.K407M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- DIPK2A | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, mutect2
- DISP3 | c.1417A>T p.I473F | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DLG2 | c.1172A>G p.E391G | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DLG2 | c.608T>A p.L203* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- DLGAP4 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 155/493 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DMRT2 | c.353G>T p.S118I | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- DNAH10 | c.2971A>C p.K991Q (on ENST00000409039; = p.K930Q on NM_207437.3) | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DNAH10 | c.3956A>G p.Q1319R (on ENST00000409039; = p.Q1258R on NM_207437.3) | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH10 | c.8219A>T p.Q2740L (on ENST00000409039; = p.Q2679L on NM_207437.3) | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, varscan2
- DNAH10 | c.10942A>T p.N3648Y (on ENST00000409039; = p.N3587Y on NM_207437.3) | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2
- DNAH12 | c.2887G>C p.G963R (on ENST00000351747; = p.G986R on NM_001366028.2) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.56); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH3 | c.4462G>T p.V1488L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, varscan2
- DNAH5 | c.660+2T>A p.X220_splice | Splice Site (SNP) | VAF 95/471 reads (20%) | called by muse, mutect2, varscan2
- DNAH6 | c.3096G>T p.W1032C | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.2811G>T p.Q937H | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH7 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DNAJB9 | c.513A>C p.E171D | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.012); called by muse, mutect2
- DNAL1 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNTT | c.155T>A p.L52H | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK3 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DPY19L4 | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DPY19L4 | c.960A>C p.L320F | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- DSCAM | c.5701T>G p.L1901V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, varscan2
- DSG3 | c.2473G>T p.G825C | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- DVL3 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- DZANK1 | c.1792A>C p.K598Q (on ENST00000262547 / NM_001099407.1; = p.K405Q on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); called by muse, mutect2
- EBLN1 | c.848del p.G283Vfs*19 | Frame Shift Del (DEL) | VAF 48/270 reads (18%) | called by mutect2, pindel, varscan2
- ECI2 | c.602A>T p.D201V (on ENST00000380118 / NM_206836.3; = p.D171V on NM_006117.2) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- EDN3 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EI24 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- EIF3B | c.424del p.A142Rfs*22 | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | called by mutect2, pindel, varscan2
- EIF3H | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- EIF3J | c.288A>C p.K96N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ELFN2 | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELK4 | c.484C>G p.L162V | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2
- EMB | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ENOX1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EOMES | c.1480A>G p.R494G | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPB41L3 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- EPHA5 | c.2629A>T p.R877* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- ERICH1 | c.1154A>T p.D385V | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESCO1 | c.2007G>T p.M669I | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ETNPPL | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 34/144 reads (24%) | called by muse, mutect2, varscan2
- EYA1 | c.658A>T p.S220C | Missense Mutation (SNP) | VAF 63/527 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- F2 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 96/340 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- FAM186B | c.1481T>A p.L494Q | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FAM200B | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- FAM222B | c.835A>T p.R279W | Missense Mutation (SNP) | VAF 36/369 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FAM83C | c.1956T>G p.N652K | Missense Mutation (SNP) | VAF 64/456 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FANCB | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- FBF1 | c.1573+2T>A p.X525_splice (on ENST00000586717; = p.X539_splice on NM_001319193.1) | Splice Site (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- FBLN7 | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FBN2 | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 96/307 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- FBXL18 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- FBXO42 | c.1332G>C p.L444F | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FBXW10 | c.1839G>T p.K613N | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FEZ1 | c.729C>G p.I243M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FMR1NB | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 69/136 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- FNBP4 | c.1363A>C p.K455Q | Missense Mutation (SNP) | VAF 44/469 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- FOXD2 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FOXF2 | c.287G>C p.R96P | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FREM2 | c.3389G>T p.G1130V | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMD4B | c.784G>C p.V262L | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- FSIP2 | c.11059C>A p.L3687I | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FXYD2 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 73/355 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- FZD1 | c.797C>G p.A266G | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD2 | c.1084C>A p.H362N | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- GABRA4 | c.130T>C p.C44R | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- GABRA4 | c.129G>T p.L43F | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- GAD1 | c.1608C>A p.H536Q | Missense Mutation (SNP) | VAF 50/410 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GALR2 | c.876C>A p.Y292* | Nonsense Mutation (SNP) | VAF 66/606 reads (11%) | called by muse, mutect2, varscan2
- GAPDH | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.231); called by muse, mutect2
- GBF1 | c.2562G>T p.E854D (on ENST00000369983 / NM_001377137.1; = p.E853D on NM_004193.3) | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- GGTLC2 | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 118/607 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- GIT2 | c.756G>T p.M252I | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GJA5 | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 97/498 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GNAL | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- GNL2 | c.1315G>T p.D439Y | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GOLGA6L9 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 71/441 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, varscan2
- GPIHBP1 | c.392_393insA p.C131* | Nonsense Mutation (INS) | VAF 150/460 reads (33%) | called by mutect2, pindel*, varscan2
- GPR158 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GPR162 | c.997G>T p.D333Y (on ENST00000311268 / NM_019858.2; = p.D49Y on NM_014449.2) | Missense Mutation (SNP) | VAF 153/320 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRAMD1B | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK2 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- GRIK4 | c.1793G>T p.W598L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GRIN2A | c.4006C>T p.L1336F | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- GYS1 | c.878T>C p.F293S | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2
- GZMM | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- H3C3 | c.289T>A p.C97S | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- H4C7 | c.22G>T p.G8* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | called by muse, mutect2, varscan2
- HAAO | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- HCN4 | c.2535C>G p.S845R | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- HDHD2 | c.408T>G p.D136E | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- HELLS | c.2029G>C p.G677R | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HEPHL1 | c.1285T>A p.W429R | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- HERC2 | c.5878A>T p.T1960S | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HFM1 | c.3168T>A p.S1056R | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- HGFAC | c.1787_1788insT p.D597Gfs*24 | Frame Shift Ins (INS) | VAF 19/107 reads (18%) | called by mutect2, pindel, varscan2
- HIPK2 | c.1689G>T p.Q563H | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HIVEP3 | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); called by muse, mutect2
- HLTF | c.1160+1G>T p.X387_splice | Splice Site (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- HMCN1 | c.15721C>A p.P5241T | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- HMCN2 | c.10463G>T p.G3488V | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGCLL1 | c.781A>T p.R261* | Nonsense Mutation (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- HNF1A | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 140/671 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- HNRNPH2 | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOATZ | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 109/494 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA1 | c.970G>C p.G324R | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HRNR | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 72/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HS3ST3B1 | c.266C>A p.P89Q | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- HSPH1 | c.2474A>C p.E825A | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR5A | c.336G>T p.R112S | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HYKK | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDH1 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IFNL1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- IGHV4-28 | c.186del p.K63Rfs*29 | Frame Shift Del (DEL) | VAF 108/879 reads (12%) | called by mutect2, pindel, varscan2
- IGHV6-1 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2
- IGHV7-81 | c.220A>C p.T74P | Missense Mutation (SNP) | VAF 108/475 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- IGKV2D-30 | c.264C>G p.S88R | Missense Mutation (SNP) | VAF 58/491 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.244); called by muse, varscan2
- IGLV1-36 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IGLV3-32 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IL16 | c.3053C>A p.P1018H (on ENST00000302987 / NM_172217.5; = p.P317H on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/406 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- IL1RAPL1 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- IL37 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IL37 | c.514C>A p.H172N | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- IMPG1 | c.602C>G p.P201R | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- ITGA8 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITK | c.1463G>T p.C488F | Missense Mutation (SNP) | VAF 106/354 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPKB | c.1596G>T p.W532C | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITPRID1 | c.1927A>G p.I643V | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAG1 | c.2537G>T p.C846F | Missense Mutation (SNP) | VAF 143/490 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JARID2 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 80/226 reads (35%) | called by muse, mutect2, varscan2
- JMJD1C | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- JPH2 | c.719G>C p.G240A | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KAT2A | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- KCNAB2 | c.977A>T p.N326I | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- KCNU1 | c.2531del p.P844Qfs*22 | Frame Shift Del (DEL) | VAF 27/145 reads (19%) | called by mutect2, pindel, varscan2
- KCTD4 | c.490T>G p.F164V | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- KDM5C | c.2815G>T p.A939S | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- KIAA0232 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- KIF27 | c.1617A>G p.I539M | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- KIR2DS4 | c.503C>G p.A168G | Missense Mutation (SNP) | VAF 84/432 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- KIR3DL2 | c.752A>T p.D251V | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- KIRREL2 | c.2057C>A p.P686H | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- KLHL1 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KLHL14 | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- KLHL23 | c.1451A>C p.E484A | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- KLHL40 | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- KNTC1 | c.1019C>A p.T340K | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2
- KRT222 | c.742T>G p.S248A | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KRT81 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- KRT82 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 51/196 reads (26%) | called by muse, mutect2, varscan2
- KRT85 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- LAMB4 | c.152T>A p.L51Q | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LATS2 | c.2666G>T p.G889V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LCE1A | c.7T>A p.C3S | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- LCOR | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- LEO1 | c.1791_1792insT p.I598Yfs*14 | Frame Shift Ins (INS) | VAF 11/99 reads (11%) | called by mutect2, pindel, varscan2
- LEO1 | c.1232G>A p.R411K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LGI1 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 129/494 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LGSN | c.1441A>C p.I481L | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- LHX3 | c.10del p.E4Kfs*169 | Frame Shift Del (DEL) | VAF 39/214 reads (18%) | called by mutect2, pindel, varscan2
- LHX8 | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.737); called by muse, varscan2
- LIG1 | c.1267A>T p.K423* | Nonsense Mutation (SNP) | VAF 30/275 reads (11%) | called by muse, mutect2, varscan2
- LILRA6 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 53/454 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIMCH1 | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LNPEP | c.1426A>C p.T476P | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPAR5 | c.718C>T p.L240F | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPO | c.100del p.I34Sfs*5 | Frame Shift Del (DEL) | VAF 24/192 reads (13%) | called by mutect2, varscan2
- LRCH3 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1 | c.7597G>T p.A2533S | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRP1B | c.11083G>T p.G3695* | Nonsense Mutation (SNP) | VAF 24/212 reads (11%) | called by muse, mutect2, varscan2
- LRP2 | c.13096G>A p.E4366K | Missense Mutation (SNP) | VAF 93/472 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- LRP4 | c.3833C>T p.A1278V | Missense Mutation (SNP) | VAF 124/539 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- LRRC32 | c.1283C>A p.P428Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC37A3 | c.1306C>A p.Q436K | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by mutect2, varscan2
- LRRC47 | c.1515A>C p.E505D | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRRD1 | c.2348G>T p.C783F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- LRRTM1 | c.937G>T p.G313W | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRTM4 | c.196T>A p.L66I | Missense Mutation (SNP) | VAF 90/337 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTBP1 | c.2011G>A p.V671M (on ENST00000404816 / NM_206943.4; = p.V345M on NM_000627.4) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2
- LTBP4 | c.1541C>T p.P514L (on ENST00000308370 / NM_001042544.1; = p.P477L on NM_003573.2) | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTN1 | c.1263G>T p.Q421H | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- LURAP1 | c.474A>T p.E158D | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MAGEC3 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 97/228 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- MALRD1 | c.6002C>T p.P2001L | Missense Mutation (SNP) | VAF 90/281 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- MAP2K3 | c.187G>T p.D63Y (on ENST00000342679 / NM_145109.3; = p.D34Y on NM_002756.4) | Missense Mutation (SNP) | VAF 52/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MAP3K19 | c.3964T>A p.S1322T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MAP4K3 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCHR2 | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED16 | c.2371C>A p.P791T | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF10 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- MEOX1 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MGAM2 | c.4727T>C p.L1576P | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAT1 | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MGAT5B | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MGAT5B | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MINK1 | c.609T>G p.D203E | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2
- MKNK2 | c.1159A>G p.S387G | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MLLT10 | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- MMP16 | c.1515G>T p.K505N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MMRN1 | c.651dup p.L218Vfs*41 | Frame Shift Ins (INS) | VAF 29/135 reads (21%) | called by pindel, varscan2
- MMUT | c.961A>T p.K321* | Nonsense Mutation (SNP) | VAF 18/191 reads (9%) | called by muse, mutect2, varscan2
- MORF4L1 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRC1 | c.414G>T p.R138S | Missense Mutation (SNP) | VAF 86/572 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MROH1 | c.4567C>A p.P1523T | Missense Mutation (SNP) | VAF 68/1104 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- MROH5 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRPL10 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- MSH4 | c.539del p.N180Tfs*18 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- MTCL1 | c.1720G>A p.V574M (on ENST00000306329 / NM_001378206.1; = p.V214M on NM_015210.4) | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR8 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- MTTP | c.2055C>G p.N685K | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MUC16 | c.42737C>A p.T14246K | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- MUC17 | c.12205G>T p.A4069S | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC21 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 208/666 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, varscan2
- MUC22 | c.5092T>C p.Y1698H | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MUC6 | c.1320C>A p.D440E | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- MUSK | c.16A>T p.N6Y | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.456); called by muse, varscan2
- MXRA5 | c.7500C>A p.N2500K | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH2 | c.4227T>G p.H1409Q | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYH8 | c.1177C>A p.L393M | Missense Mutation (SNP) | VAF 109/436 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- MYL3 | c.482-1G>T p.X161_splice | Splice Site (SNP) | VAF 56/245 reads (23%) | called by muse, mutect2, varscan2
- MYO18B | c.6189G>T p.R2063S | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MYO7A | c.4054A>G p.T1352A | Missense Mutation (SNP) | VAF 63/431 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MYOM3 | c.2629C>A p.Q877K | Missense Mutation (SNP) | VAF 58/283 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MYSM1 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- NAV3 | c.5167dup p.T1723Nfs*9 | Frame Shift Ins (INS) | VAF 51/345 reads (15%) | called by mutect2, pindel, varscan2
- NCAPD3 | c.2004G>T p.W668C | Missense Mutation (SNP) | VAF 59/271 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA5 | c.366G>T p.R122S | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NEB | c.1819A>C p.K607Q | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2
- NELL1 | c.1286C>A p.S429Y | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- NFIB | c.1031_1035dup p.G346Ifs*50 | Frame Shift Ins (INS) | VAF 38/211 reads (18%) | called by mutect2, varscan2
- NHS | c.2326A>C p.N776H | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- NINL | c.3511G>T p.E1171* | Nonsense Mutation (SNP) | VAF 55/392 reads (14%) | called by muse, mutect2, varscan2
- NLRP12 | c.1180A>C p.N394H | Missense Mutation (SNP) | VAF 144/760 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- NLRP2 | c.3172C>T p.H1058Y | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NLRP5 | c.902T>A p.L301Q | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRXN1 | c.1256G>A p.S419N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRXN3 | c.1019A>C p.N340T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- NUCKS1 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NUP210L | c.2155T>A p.Y719N | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUP37 | c.321T>G p.F107L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NWD1 | c.4514C>A p.S1505* | Nonsense Mutation (SNP) | VAF 101/382 reads (26%) | called by muse, mutect2, varscan2
- OLIG1 | c.9T>A p.Y3* | Nonsense Mutation (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- OPLAH | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 65/152 reads (43%) | called by muse, mutect2, varscan2
- OPN5 | c.955G>C p.G319R | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- OPRD1 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10T2 | c.584T>A p.V195E | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- OR1J1 | c.513C>G p.D171E | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR1J1 | c.299del p.Q100Rfs*11 | Frame Shift Del (DEL) | VAF 47/244 reads (19%) | called by mutect2, pindel, varscan2
- OR4A47 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR4F5 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 140/493 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4X2 | c.860G>T p.R287M | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2
- OR6P1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8J3 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ORM2 | c.260A>G p.Q87R | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- OS9 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSBPL1A | c.2153G>T p.G718V (on ENST00000319481 / NM_080597.4; = p.G205V on NM_018030.4) | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL9 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- OSR2 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- OTUD6A | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OXCT1 | c.1469G>T p.W490L | Missense Mutation (SNP) | VAF 86/359 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PABPC4 | c.1219G>T p.G407C | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, varscan2
- PAK6 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | called by muse, varscan2
- PALM2AKAP2 | c.2375C>G p.P792R (on ENST00000259318 / NM_001136562.3; = p.P1023R on NM_007203.5) | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PAPPA | c.2198G>T p.S733I | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PARP8 | c.1625G>T p.G542V | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PAXBP1 | c.2744A>C p.E915A | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCDH15 | c.2507C>A p.T836N | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PCDH18 | c.3214C>G p.P1072A | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA2 | c.1991C>A p.T664N | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PCDHA5 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA9 | c.1857C>A p.S619R | Missense Mutation (SNP) | VAF 98/386 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGB7 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCED1B | c.151dup p.R51Kfs*10 | Frame Shift Ins (INS) | VAF 24/90 reads (27%) | called by mutect2, pindel, varscan2
- PCK1 | c.1399G>C p.A467P | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCLO | c.7672A>T p.T2558S | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PCM1 | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCNX2 | c.4394G>T p.G1465V | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- PDGFRA | c.2100G>C p.K700N | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PEAR1 | c.1214A>T p.Q405L | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEX2 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 34/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHF13 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PHF20L1 | c.152G>T p.S51I | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PIGU | c.826_848del p.Y276Afs*44 | Frame Shift Del (DEL) | VAF 28/288 reads (10%) | called by mutect2, pindel
- PIK3C2B | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PIK3C2G | c.3389C>A p.P1130Q (on ENST00000676171; = p.P1089Q on NM_004570.5) | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PIK3R5 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PIK3R6 | c.2224C>T p.L742F | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PILRB | c.331A>T p.R111W | Missense Mutation (SNP) | VAF 122/453 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- PIWIL3 | c.544T>G p.L182V | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- PJA1 | c.619T>C p.S207P | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.3064G>T p.D1022Y | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PLAGL2 | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 145/312 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLCXD3 | c.425T>A p.L142* | Nonsense Mutation (SNP) | VAF 82/311 reads (26%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- POLR1A | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- POU5F1B | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 121/326 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- POU5F1B | c.704C>A p.T235N | Missense Mutation (SNP) | VAF 336/820 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- PPP1R12C | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 52/251 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PPP1R16B | c.878C>A p.S293Y | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PPP2R3B | c.1568G>C p.W523S | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PRAMEF10 | c.471A>C p.E157D | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, varscan2
- PRAMEF7 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 44/840 reads (5%) | called by muse, mutect2
- PRDM13 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM9 | c.676A>T p.K226* | Nonsense Mutation (SNP) | VAF 94/426 reads (22%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.2314C>A p.P772T (on ENST00000295902; = p.P716T on NM_198859.4) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRKAA2 | c.1424A>C p.E475A | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- PRKAG2 | c.1126T>G p.S376A | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.076); called by muse, varscan2
- PRKD1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PRKDC | c.2860G>T p.G954* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- PRKG1 | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRMT5 | c.414G>C p.L138F | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PRR11 | c.234T>A p.N78K | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PSG2 | c.625A>C p.K209Q | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PSMB8 | c.295+1G>T p.X99_splice (on ENST00000374882 / NM_148919.4; = p.X95_splice on NM_004159.5) | Splice Site (SNP) | VAF 11/237 reads (5%) | called by muse, mutect2
- PTDSS1 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRB | c.4667G>T p.G1556V | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRB | c.4666G>T p.G1556C | Missense Mutation (SNP) | VAF 68/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRH | c.1894G>T p.V632L | Missense Mutation (SNP) | VAF 32/471 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); called by muse, mutect2
- PTPRT | c.340A>T p.R114W | Missense Mutation (SNP) | VAF 146/371 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- PTPRZ1 | c.6850A>T p.S2284C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PUM1 | c.2934del p.I978Mfs*32 | Frame Shift Del (DEL) | VAF 26/316 reads (8%) | called by mutect2, pindel
- PXDNL | c.1091C>A p.T364N | Missense Mutation (SNP) | VAF 71/531 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- RAB3IL1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RALGAPA1 | c.772A>T p.K258* | Nonsense Mutation (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- RASA2 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- RASGRP3 | c.1834C>A p.Q612K (on ENST00000402538 / NM_001349975.2; = p.Q611K on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- RB1CC1 | c.3358G>T p.V1120L | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RBM46 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 79/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBMY1A1 | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by mutect2, varscan2
- RBP3 | c.2740C>A p.P914T | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFNG | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.031); called by muse, mutect2
- RFX6 | c.2446T>C p.S816P | Missense Mutation (SNP) | VAF 116/308 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RFX7 | c.3285T>G p.N1095K (on ENST00000559447 / NM_001368074.1; = p.N1192K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- RGS3 | c.1673A>T p.Q558L (on ENST00000350696 / NM_001282923.2; = p.Q446L on NM_017790.4) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RIMS2 | c.2410C>A p.H804N (on ENST00000666250 / NM_001348490.2; = p.H612N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF139 | c.817T>A p.F273I | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2
- RP1 | c.3931del p.S1311Lfs*35 | Frame Shift Del (DEL) | VAF 86/708 reads (12%) | called by pindel, varscan2
- RPH3A | c.219G>T p.Q73H (on ENST00000389385 / NM_001143854.2; = p.Q69H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RPH3A | c.1376G>T p.W459L (on ENST00000389385 / NM_001143854.2; = p.W455L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/330 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RPRD2 | c.3987T>A p.S1329R | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); called by muse, mutect2
- RPS6KL1 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RUSC1 | c.1625G>C p.G542A (on ENST00000368352 / NM_001105203.2; = p.G73A on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR3 | c.2983G>T p.A995S | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RYR3 | c.3309G>T p.W1103C | Missense Mutation (SNP) | VAF 92/314 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SALL1 | c.3929G>T p.R1310L | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- SARM1 | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SBK2 | c.733G>T p.D245Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN1A | c.5586C>G p.I1862M (on ENST00000303395 / NM_001202435.3; = p.I1851M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SCN2A | c.2148A>T p.E716D | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- SCN3A | c.3604A>G p.I1202V | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN3A | c.3151A>G p.N1051D | Missense Mutation (SNP) | VAF 66/326 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- SCN3A | c.2299A>T p.T767S | Missense Mutation (SNP) | VAF 41/405 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SCN7A | c.4276T>A p.C1426S | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SDK1 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.121); called by muse, mutect2
- SDSL | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEC11A | c.506dup p.L169Ffs*11 | Frame Shift Ins (INS) | VAF 37/179 reads (21%) | called by mutect2, pindel, varscan2
- SESN1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH2D5 | c.1108del p.E370Rfs*19 (on ENST00000444387 / NM_001103161.2; = p.E286Rfs*19 on NM_001103160.2) | Frame Shift Del (DEL) | VAF 16/140 reads (11%) | called by mutect2, pindel*, varscan2
- SHANK3 | c.3016G>T p.G1006C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- SHROOM2 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SIGLEC6 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
531 further variants in this file (141 protein-altering or splice-affecting, 235 silent, 155 other) are not listed here.
